Somatic mutation profile of tumor specimen ALCH-AEO2-TTP1-A (aliquot ALCH-AEO2-TTP1-A-1-0-D-A636-36) from ALCHEMIST case ALCH-AEO2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.7 years (23,979 days).
Specimen ALCH-AEO2-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11d1e8ec-4570-46c6-9381-2ae24a7e70f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEO2-NB1-A (Blood Derived Normal), aliquot ALCH-AEO2-NB1-A-2-0-D-A635-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25f15932-e10d-4fd6-a04a-93fc7572a844

The open-access MAF lists 361 somatic variants for this specimen: 235 protein-altering or splice-affecting, 86 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 201, Silent 86, Intron 17, Nonsense Mutation 14, RNA 14, Splice Site 7, Frame Shift Del 6, 3'UTR 4, Splice Region 4, 5'UTR 3, Frame Shift Ins 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LGI4 | c.1031T>A p.L344Q | Missense Mutation (SNP) | VAF 61/224 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs1201430967; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PANK3 | c.901A>T p.I301F | Missense Mutation (SNP) | VAF 14/142 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs77612793; called by mutect2, varscan2
- TP53 | c.472C>A p.R158S | Missense Mutation (SNP) | VAF 47/303 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM004341, CM121763, COSV52677865, COSV52699654, COSV52778687; called by muse, mutect2, varscan2
- A3GALT2 | c.838C>A p.R280S | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs1484096575; called by muse, mutect2, varscan2
- ABCB1 | c.3070G>T p.E1024* | Nonsense Mutation (SNP) | VAF 100/1094 reads (9%) | catalogued as COSV55948316; called by muse, mutect2
- ABCB5 | c.130G>T p.D44Y | Missense Mutation (SNP) | VAF 38/360 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as rs747677706; called by muse, mutect2, varscan2
- ACRBP | c.1442A>G p.Y481C | Missense Mutation (SNP) | VAF 43/375 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.635); catalogued as rs1377102670; called by muse, mutect2, varscan2
- ADAM12 | c.2264C>A p.S755Y | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); catalogued as COSV100900591; called by muse, mutect2
- AK7 | c.1339A>T p.S447C | Missense Mutation (SNP) | VAF 31/299 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs1347185688; called by muse, mutect2, varscan2
- AR | c.1736G>T p.S579I | Missense Mutation (SNP) | VAF 60/624 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM003404, CM105634, CM1515323; called by muse, mutect2
- BBS9 | c.2471G>T p.R824L (on ENST00000242067 / NM_001348036.1; = p.R784L on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 117/1017 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV99629929; called by muse, mutect2, varscan2
- BRINP3 | c.1222C>A p.L408I | Missense Mutation (SNP) | VAF 32/236 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV100819582; called by muse, varscan2
- C2orf16 | c.2603C>T p.P868L | Missense Mutation (SNP) | VAF 33/310 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772554173; called by muse, mutect2, varscan2
- CEP162 | c.2729G>A p.R910H | Missense Mutation (SNP) | VAF 42/442 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as rs370857486; called by muse, mutect2
- CILP2 | c.2746G>T p.E916* | Nonsense Mutation (SNP) | VAF 40/150 reads (27%) | catalogued as COSV99364205; called by muse, mutect2, varscan2
- COL6A5 | c.5590G>T p.V1864L (on ENST00000312481; = p.V1860L on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/858 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as rs374300805; called by muse, mutect2
- CYP4F11 | c.1231G>A p.G411S | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as rs1294622238; called by muse, mutect2, varscan2
- DCAF8L2 | c.1691G>T p.R564L | Missense Mutation (SNP) | VAF 19/209 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as rs1403423572, COSV70551548; called by muse, mutect2
- DRC7 | c.1552T>C p.S518P | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs745452424; called by muse, mutect2
- EPHA3 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 81/399 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.21); catalogued as COSV60706061; called by muse, mutect2, varscan2
- FAM135B | c.4071G>C p.K1357N | Missense Mutation (SNP) | VAF 76/759 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs201744533, COSV52739067, COSV52745902, COSV99426511; called by muse, mutect2, varscan2
- FLT1 | c.941G>T p.R314M | Missense Mutation (SNP) | VAF 48/583 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as COSV56723759, COSV56741933; called by muse, mutect2
- GAB4 | c.1469T>A p.L490H | Missense Mutation (SNP) | VAF 34/242 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV101271993, COSV68755240; called by muse, mutect2, varscan2
- HCN1 | c.1643G>T p.R548L | Missense Mutation (SNP) | VAF 64/452 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV57514030; called by muse, mutect2, varscan2
- HGF | c.589C>G p.R197G | Missense Mutation (SNP) | VAF 54/539 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV55949853; called by muse, mutect2, varscan2
- INPP5A | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 62/642 reads (10%) | catalogued as rs768610955, COSV100704507, COSV61251497; called by muse, mutect2
- IQSEC1 | c.2168A>G p.Q723R | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV99832504; called by muse, mutect2
- KCNQ2 | c.427G>T p.V143L | Missense Mutation (SNP) | VAF 28/240 reads (12%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.999); catalogued as rs768237205, COSV60435850; called by muse, varscan2
- KEAP1 | c.1801C>G p.R601G | Missense Mutation (SNP) | VAF 42/344 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV50260672; called by muse, mutect2, varscan2
- KIR3DL2 | c.770G>C p.R257T | Missense Mutation (SNP) | VAF 126/538 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54390378; called by muse, mutect2, varscan2
- KLC1 | c.1650+2dup p.X550_splice | Splice Site (INS) | VAF 14/142 reads (10%) | catalogued as rs1567034128; called by mutect2, pindel, varscan2
- KLHL32 | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.958); catalogued as rs878977821, COSV65114168; called by muse, mutect2, varscan2
- LARP4B | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 32/268 reads (12%) | catalogued as COSV60222613; called by muse, varscan2
- LEPR | c.2480G>A p.S827N | Missense Mutation (SNP) | VAF 45/363 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.093); catalogued as COSV60760052; called by muse, mutect2, varscan2
- MGMT | c.472G>T p.A158S (on ENST00000306010; = p.A127S on NM_002412.5) | Missense Mutation (SNP) | VAF 79/549 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.432); catalogued as COSV60024669; called by muse, mutect2, varscan2
- MRTFA | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 49/337 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs138116355; called by muse, mutect2, varscan2
- MXRA5 | c.4762C>T p.R1588C | Missense Mutation (SNP) | VAF 32/431 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV54231857; called by muse, mutect2
- MYH6 | c.1014C>A p.D338E | Missense Mutation (SNP) | VAF 82/676 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as rs763533477; called by muse, mutect2, varscan2
- NCKAP1L | c.2450G>T p.S817I | Missense Mutation (SNP) | VAF 45/504 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV53208142; called by muse, mutect2
- NKD2 | c.1012G>T p.G338W | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776447917; called by muse, mutect2, varscan2
- NTRK3 | c.1592A>T p.Q531L | Missense Mutation (SNP) | VAF 81/692 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV100714019; called by muse, mutect2, varscan2
- OR4C6 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 40/382 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.066); catalogued as rs146965889, COSV100051763; called by muse, mutect2, varscan2
- OTOGL | c.5385G>T p.Q1795H (on ENST00000547103; = p.Q1786H on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV54020430; called by muse, mutect2, varscan2
- PCDH15 | c.5185C>T p.P1729S (on ENST00000644397 / NM_001354429.2; = p.P1671S on NM_001142771.2) | Missense Mutation (SNP) | VAF 39/313 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100903407, COSV100904782; called by muse, mutect2, varscan2
- PEG3 | c.1474G>C p.V492L | Missense Mutation (SNP) | VAF 210/623 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.53); catalogued as rs1184508853, COSV55645657; called by muse, mutect2, varscan2
- PGR | c.2219G>A p.R740Q | Missense Mutation (SNP) | VAF 35/325 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs149186732; called by muse, mutect2, varscan2
- PIK3R1 | c.2083G>A p.V695M (on ENST00000521381 / NM_181523.3; = p.V425M on NM_181504.4) | Missense Mutation (SNP) | VAF 62/455 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57129147; called by muse, mutect2, varscan2
- PLCZ1 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 98/895 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56856157; called by muse, mutect2, varscan2
- PRR16 | c.202G>C p.E68Q (on ENST00000407149 / NM_001300783.2; = p.E45Q on NM_016644.2) | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101086099; called by muse, mutect2, varscan2
- RAF1 | c.572G>T p.R191I | Missense Mutation (SNP) | VAF 41/477 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.158); catalogued as CM101369, COSV52583482; called by muse, mutect2
- RANBP2 | c.9244A>G p.M3082V | Missense Mutation (SNP) | VAF 45/365 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.116); catalogued as rs757924944; called by muse, mutect2, varscan2
- RIMS2 | c.2860A>G p.S954G (on ENST00000666250 / NM_001348490.2; = p.S762G on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/314 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.139); catalogued as rs1409088068; called by muse, mutect2, varscan2
- RNF111 | c.523A>G p.R175G | Missense Mutation (SNP) | VAF 28/351 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.11); catalogued as rs1399189461; called by muse, mutect2
- RNF213 | c.13933G>A p.V4645I | Missense Mutation (SNP) | VAF 52/393 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as rs868024819; called by muse, mutect2, varscan2
- RYR2 | c.10430G>T p.G3477V | Missense Mutation (SNP) | VAF 35/234 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63717226; called by muse, mutect2, varscan2
- SCN3A | c.1115C>G p.A372G | Missense Mutation (SNP) | VAF 49/437 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV51810702; called by muse, mutect2, varscan2
- SFI1 | c.3032G>T p.R1011L (on ENST00000400288 / NM_001007467.3; = p.R980L on NM_014775.4) | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV56718094; called by muse, mutect2, varscan2
- SLITRK4 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 41/379 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62025069; called by muse, mutect2, varscan2
- SNX1 | c.215C>G p.S72C | Missense Mutation (SNP) | VAF 42/321 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs150183282; called by muse, mutect2, varscan2
- SPATA31A1 | c.3307A>G p.M1103V | Missense Mutation (SNP) | VAF 75/1490 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.29); catalogued as rs745536637; called by muse, mutect2
- SRPX | c.760C>T p.R254* | Nonsense Mutation (SNP) | VAF 24/252 reads (10%) | catalogued as rs751611641, COSV59441460; called by muse, mutect2, varscan2
- SVEP1 | c.3454G>A p.A1152T | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371612398; called by muse, mutect2, varscan2
- SYP | c.133G>T p.G45C | Missense Mutation (SNP) | VAF 36/426 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782140208, COSV54296635; called by muse, mutect2
- TAF3 | c.2735G>T p.C912F | Missense Mutation (SNP) | VAF 53/640 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60204129; called by muse, mutect2
- TECRL | c.793C>A p.H265N | Missense Mutation (SNP) | VAF 26/262 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs1388021394, COSV101169369; called by muse, mutect2, varscan2
- TECRL | c.592C>A p.L198I | Missense Mutation (SNP) | VAF 47/416 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1409531996, COSV101169360; called by muse, varscan2
- TEX13C | c.1316G>A p.S439N | Missense Mutation (SNP) | VAF 76/782 reads (10%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.986); catalogued as rs1383284528; called by muse, mutect2
- THBD | c.1522C>G p.P508A | Missense Mutation (SNP) | VAF 41/369 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.265); catalogued as rs1212697906; called by muse, mutect2, varscan2
- TLE4 | c.1630G>C p.D544H | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1350400905; called by muse, mutect2
- TNR | c.3667C>T p.R1223C | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760079630; called by muse, mutect2, varscan2
- TPO | c.1535C>A p.P512H | Missense Mutation (SNP) | VAF 40/322 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs150489706; called by muse, varscan2
- TRIML2 | c.539C>A p.A180D | Missense Mutation (SNP) | VAF 44/444 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as rs775984097; called by muse, mutect2
- TTN | c.68411C>A p.T22804N (on ENST00000591111; = p.T15380N on NM_003319.4) | Missense Mutation (SNP) | VAF 27/218 reads (12%) | PolyPhen probably damaging (0.997); catalogued as rs377334665; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.18830A>C p.K6277T (on ENST00000591111; = p.K5350T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/154 reads (13%) | PolyPhen benign (0.206); catalogued as COSV100611629; called by muse, mutect2, varscan2
- UBQLNL | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 59/658 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV66494793; called by muse, mutect2
- VAPA | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 28/329 reads (9%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.466); catalogued as rs759982166, COSV61297362; called by muse, mutect2
- VPS8 | c.256G>T p.D86Y | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54987270; called by muse, mutect2
- VWA3A | c.2330del p.P777Rfs*2 | Frame Shift Del (DEL) | VAF 27/278 reads (10%) | catalogued as rs751355756; called by mutect2, pindel
- ZFAND6 | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 47/323 reads (15%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.992); catalogued as rs141077255; called by muse, mutect2, varscan2
- ZFHX3 | c.10598C>T p.A3533V | Missense Mutation (SNP) | VAF 49/373 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.392); catalogued as rs776065671, COSV51706759; called by muse, mutect2, varscan2
- ZFYVE9 | c.3283C>T p.R1095W | Missense Mutation (SNP) | VAF 48/520 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55091516; called by muse, mutect2
- ZNF607 | c.596G>C p.C199S | Missense Mutation (SNP) | VAF 25/237 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62206766; called by muse, mutect2, varscan2
- ZP4 | c.840-2A>G p.X280_splice | Splice Site (SNP) | VAF 27/238 reads (11%) | catalogued as rs1422581725; called by muse, mutect2, varscan2
- ABCC6 | c.1795G>T p.D599Y | Missense Mutation (SNP) | VAF 74/690 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- ABCC6 | c.1385T>G p.L462R | Missense Mutation (SNP) | VAF 58/577 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ABCG5 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 35/262 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- AC053503.6 | c.864G>T p.K288N | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- ADCY9 | c.3643G>T p.V1215F | Missense Mutation (SNP) | VAF 57/542 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- ADGRD2 | c.2856G>T p.M952I | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADGRL2 | c.3754C>G p.L1252V (on ENST00000370717 / NM_001366005.1; = p.L1196V on NM_012302.4) | Missense Mutation (SNP) | VAF 46/548 reads (8%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.566); called by muse, mutect2
- ALDOC | c.622A>C p.K208Q | Missense Mutation (SNP) | VAF 56/441 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- AMPD1 | c.622G>T p.V208L | Missense Mutation (SNP) | VAF 68/532 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMY2B | c.786C>A p.Y262* | Nonsense Mutation (SNP) | VAF 133/820 reads (16%) | called by muse, mutect2, varscan2
- ANKRD30B | c.3089A>T p.K1030I | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ARMC1 | c.196T>A p.L66M | Missense Mutation (SNP) | VAF 58/450 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATRX | c.5790G>T p.K1930N | Missense Mutation (SNP) | VAF 37/483 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2
- AURKC | c.704G>C p.G235A (on ENST00000302804 / NM_001015878.2; = p.G201A on NM_003160.3) | Missense Mutation (SNP) | VAF 41/482 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- B3GAT1 | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); called by muse, mutect2
- C1orf115 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C1orf198 | c.831G>T p.E277D | Missense Mutation (SNP) | VAF 25/225 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC150 | c.893-1G>T p.X298_splice | Splice Site (SNP) | VAF 32/246 reads (13%) | called by muse, mutect2, varscan2
- CDC123 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 61/516 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- CEP89 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 166/546 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP46 | c.2263G>T p.G755W | Missense Mutation (SNP) | VAF 42/400 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CHRNA3 | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 40/266 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CHRNA7 | c.1238C>T p.S413F | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); called by mutect2, varscan2
- CNTN3 | c.2659G>C p.A887P | Missense Mutation (SNP) | VAF 29/270 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CNTN5 | c.2143G>T p.G715C | Missense Mutation (SNP) | VAF 31/248 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL25A1 | c.1414C>A p.P472T | Missense Mutation (SNP) | VAF 32/308 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- CPA3 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CSNK1E | c.809G>C p.R270P | Missense Mutation (SNP) | VAF 22/607 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CSPG4 | c.5036C>A p.S1679Y | Missense Mutation (SNP) | VAF 22/249 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2
- CST2 | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 68/643 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.112); called by muse, mutect2
- CXCR3 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- CYP17A1 | c.1277T>C p.I426T | Missense Mutation (SNP) | VAF 93/660 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- DDB2 | c.359A>T p.H120L | Missense Mutation (SNP) | VAF 42/355 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHX8 | c.1357A>G p.T453A | Missense Mutation (SNP) | VAF 36/283 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- DHX8 | c.2573G>T p.G858V | Missense Mutation (SNP) | VAF 39/422 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DMD | c.5745T>G p.I1915M | Missense Mutation (SNP) | VAF 56/407 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- EBF4 | c.358+1G>T p.X120_splice (on ENST00000609451; = p.X116_splice on NM_001110514.1) | Splice Site (SNP) | VAF 15/194 reads (8%) | called by muse, mutect2
- ELAVL2 | c.230-1G>A p.X77_splice | Splice Site (SNP) | VAF 44/228 reads (19%) | called by muse, mutect2, varscan2
- ENPP2 | c.1597C>A p.H533N (on ENST00000075322 / NM_001040092.3; = p.H585N on NM_006209.5) | Missense Mutation (SNP) | VAF 68/692 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2
- ERN2 | c.1611G>T p.R537= | Splice Region (SNP) | VAF 17/139 reads (12%) | called by muse, mutect2, varscan2
- ERVV-1 | c.542dup p.N181Kfs*84 | Frame Shift Ins (INS) | VAF 157/889 reads (18%) | called by mutect2, pindel, varscan2
- EYS | c.2080G>T p.A694S | Missense Mutation (SNP) | VAF 46/883 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); called by muse, mutect2
- FAM189A1 | c.220-1G>T p.X74_splice | Splice Site (SNP) | VAF 39/343 reads (11%) | called by muse, mutect2, varscan2
- FAM189B | c.841A>T p.T281S | Missense Mutation (SNP) | VAF 64/439 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- FAM53A | c.450G>C p.K150N | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FANCB | c.1922C>A p.P641H | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.794); called by muse, mutect2
- FAT1 | c.12955G>T p.D4319Y | Missense Mutation (SNP) | VAF 33/321 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- FAT3 | c.6544G>A p.A2182T | Missense Mutation (SNP) | VAF 61/577 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCGR2A | c.579C>A p.Y193* (on ENST00000271450 / NM_001136219.3; = p.Y192* on NM_021642.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 56/423 reads (13%) | called by muse, mutect2, varscan2
- FCGR3B | c.387C>A p.H129Q | Missense Mutation (SNP) | VAF 84/807 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- FLNA | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2
- FMN2 | c.869C>A p.P290H | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GALR2 | c.793C>G p.P265A | Missense Mutation (SNP) | VAF 47/434 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- GAS2L1 | c.1723G>T p.G575C | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- GASK1B | c.378G>T p.K126N | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- GBP4 | c.821G>T p.R274M | Missense Mutation (SNP) | VAF 48/429 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- GFRAL | c.457A>T p.K153* | Nonsense Mutation (SNP) | VAF 33/294 reads (11%) | called by muse, mutect2, varscan2
- GNB5 | c.845C>G p.S282C (on ENST00000261837 / NM_016194.4; = p.S240C on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/408 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- GPR149 | c.1331A>G p.D444G | Missense Mutation (SNP) | VAF 198/540 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GPT2 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 38/1300 reads (3%) | SIFT tolerated (0.82); PolyPhen benign (0.013); called by muse, mutect2
- GRB10 | c.942G>T p.L314F (on ENST00000398812; = p.L256F on NM_001001550.3) | Missense Mutation (SNP) | VAF 88/832 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HDAC8 | c.1039G>T p.E347* | Nonsense Mutation (SNP) | VAF 36/571 reads (6%) | called by muse, mutect2
- HGF | c.352C>A p.L118I | Missense Mutation (SNP) | VAF 52/513 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HIF3A | c.644del p.P215Rfs*35 (on ENST00000377670 / NM_152795.4; = p.P146Rfs*35 on NM_022462.4) | Frame Shift Del (DEL) | VAF 37/390 reads (9%) | called by mutect2, pindel
- HMCN2 | c.281C>A p.A94E | Missense Mutation (SNP) | VAF 18/384 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2
- HNRNPC | c.355A>T p.S119C | Missense Mutation (SNP) | VAF 15/210 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.035); called by muse, mutect2
- IGHG1 | c.671G>T p.G224V | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.10G>T p.G4W | Missense Mutation (SNP) | VAF 36/602 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.044); called by muse, mutect2
- IGKV1-12 | c.145C>T p.Q49* | Nonsense Mutation (SNP) | VAF 64/1001 reads (6%) | called by muse, mutect2
- IL1RAPL1 | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 48/658 reads (7%) | called by muse, mutect2
- ITGA1 | c.956G>T p.S319I | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, varscan2
- ITIH5 | c.202A>G p.T68A | Missense Mutation (SNP) | VAF 61/537 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ITPKC | c.1326G>T p.E442D | Missense Mutation (SNP) | VAF 76/752 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- JAK2 | c.855dup p.A286Cfs*19 | Frame Shift Ins (INS) | VAF 61/372 reads (16%) | called by mutect2, pindel, varscan2
- KCND2 | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 111/930 reads (12%) | called by muse, mutect2, varscan2
- KCNG3 | c.854G>T p.G285V | Missense Mutation (SNP) | VAF 41/317 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF11 | c.203T>C p.F68S | Missense Mutation (SNP) | VAF 38/269 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF5A | c.939G>T p.E313D | Missense Mutation (SNP) | VAF 114/976 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- KRT6B | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 67/847 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- KRT84 | c.1547G>T p.G516V | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- LAS1L | c.737G>A p.S246N | Missense Mutation (SNP) | VAF 56/393 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- LGR6 | c.678del p.T227Pfs*13 (on ENST00000367278 / NM_001017403.1; = p.T175Pfs*13 on NM_021636.3) | Frame Shift Del (DEL) | VAF 34/277 reads (12%) | called by mutect2, pindel, varscan2
- LILRA2 | c.391C>A p.P131T | Missense Mutation (SNP) | VAF 60/315 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LILRA2 | c.392C>A p.P131H | Missense Mutation (SNP) | VAF 60/322 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LPIN1 | c.481A>C p.K161Q | Missense Mutation (SNP) | VAF 78/776 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- LRRC18 | c.305A>G p.N102S | Missense Mutation (SNP) | VAF 48/451 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC7 | c.829A>G p.K277E (on ENST00000651989 / NM_001370785.2; = p.K244E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/366 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.179); called by muse, mutect2
- MGAM | c.1169T>C p.L390S | Missense Mutation (SNP) | VAF 47/426 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); called by muse, mutect2
- MMP19 | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- MMP27 | c.1168T>A p.F390I | Missense Mutation (SNP) | VAF 19/200 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- MYH9 | c.1497G>C p.W499C | Missense Mutation (SNP) | VAF 119/923 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NBPF11 | c.2303G>T p.R768M | Missense Mutation (SNP) | VAF 90/1116 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.803); called by muse, mutect2
- NPBWR1 | c.766A>C p.I256L | Missense Mutation (SNP) | VAF 23/252 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); called by muse, mutect2
- NSD1 | c.4259C>T p.P1420L | Missense Mutation (SNP) | VAF 50/394 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, varscan2
- NSMCE1 | c.226A>T p.T76S | Missense Mutation (SNP) | VAF 51/525 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- OR2G6 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 98/817 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- OR2M3 | c.350T>C p.V117A | Missense Mutation (SNP) | VAF 34/427 reads (8%) | SIFT tolerated (0.92); PolyPhen benign (0.007); called by muse, mutect2
- OR51B6 | c.481C>A p.L161I | Missense Mutation (SNP) | VAF 61/477 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5P3 | c.562G>T p.A188S | Missense Mutation (SNP) | VAF 48/434 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR6K3 | c.848C>G p.P283R (on ENST00000368146; = p.P267R on NM_001005327.2) | Missense Mutation (SNP) | VAF 48/502 reads (10%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.61); called by muse, mutect2
- OR6K3 | c.755C>G p.A252G (on ENST00000368146; = p.A236G on NM_001005327.2) | Missense Mutation (SNP) | VAF 53/419 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OSGIN1 | n.837G>C | Splice Region (SNP) | VAF 12/73 reads (16%) | called by muse, mutect2
- PAGE2 | c.276G>T p.E92D | Missense Mutation (SNP) | VAF 76/850 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.354); called by muse, mutect2
- PAPPA2 | c.1184T>A p.L395Q | Missense Mutation (SNP) | VAF 41/468 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- PCDHB6 | c.2147G>T p.R716M | Missense Mutation (SNP) | VAF 57/384 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- PCDHGA12 | c.559G>C p.D187H | Missense Mutation (SNP) | VAF 51/363 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- PGA5 | c.920T>C p.M307T | Missense Mutation (SNP) | VAF 97/1176 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2
- PIWIL4 | c.1705G>T p.D569Y | Missense Mutation (SNP) | VAF 106/861 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- PLCE1 | c.4906A>T p.N1636Y | Missense Mutation (SNP) | VAF 49/522 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.347); called by muse, mutect2
- PNCK | c.69-3C>A | Splice Region (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2, varscan2
- POM121L12 | c.519C>A p.C173* | Nonsense Mutation (SNP) | VAF 15/147 reads (10%) | called by muse, mutect2, varscan2
- POM121L2 | c.2733C>A p.D911E | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- PPM1H | c.527A>T p.D176V | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- PRRT4 | c.1500del p.L501Cfs*70 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by pindel, varscan2
- PTCH2 | c.617+1G>T p.X206_splice | Splice Site (SNP) | VAF 51/481 reads (11%) | called by muse, mutect2, varscan2
- PUS7 | c.187G>T p.D63Y | Missense Mutation (SNP) | VAF 41/389 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- RAPGEF2 | c.120C>A p.H40Q | Missense Mutation (SNP) | VAF 64/644 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RESF1 | c.1287G>T p.M429I | Missense Mutation (SNP) | VAF 33/332 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RNF103 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 26/262 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.152); called by muse, mutect2
- SATB2 | c.793G>T p.G265W | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- SCART1 | c.342G>T p.Q114H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.889); called by muse, varscan2
- SMC2 | c.2934A>C p.K978N | Missense Mutation (SNP) | VAF 38/540 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.168); called by muse, mutect2
- SMG1 | c.6825G>T p.W2275C | Missense Mutation (SNP) | VAF 68/676 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SNUPN | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 42/368 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- SORL1 | c.6389C>A p.A2130D | Missense Mutation (SNP) | VAF 63/492 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SPATA31D1 | c.4555C>A p.P1519T | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.133); called by muse, mutect2
- SPEG | c.9355G>T p.G3119C | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- SPRY3 | c.239G>T p.S80I | Missense Mutation (SNP) | VAF 44/584 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.588); called by muse, mutect2
- STAB2 | c.4090G>T p.D1364Y | Missense Mutation (SNP) | VAF 83/876 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- STT3B | c.263G>T p.R88L | Missense Mutation (SNP) | VAF 18/337 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- STYXL2 | c.1773del p.W592Gfs*3 | Frame Shift Del (DEL) | VAF 16/113 reads (14%) | called by mutect2, pindel*
- SUGP1 | c.1209G>T p.Q403H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.592); called by muse, varscan2
- THSD7B | c.629del p.P210Lfs*11 | Frame Shift Del (DEL) | VAF 94/752 reads (13%) | called by mutect2, pindel, varscan2
- TKTL1 | c.971T>C p.I324T | Missense Mutation (SNP) | VAF 21/417 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.081); called by muse, mutect2
- TLDC2 | c.563C>A p.S188Y | Missense Mutation (SNP) | VAF 32/351 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- TLN2 | c.1664C>T p.A555V | Missense Mutation (SNP) | VAF 47/440 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM200A | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 31/268 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- TMPRSS11B | c.382A>T p.R128W | Missense Mutation (SNP) | VAF 66/612 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- TOB1 | c.919T>G p.F307V | Missense Mutation (SNP) | VAF 63/710 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); called by muse, mutect2
- TOGARAM2 | c.2591A>T p.Y864F | Missense Mutation (SNP) | VAF 71/584 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- TRIM63 | c.641A>T p.D214V | Missense Mutation (SNP) | VAF 43/355 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- TRIM66 | c.1215G>C p.Q405H | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRMT9B | c.542G>A p.C181Y | Missense Mutation (SNP) | VAF 30/209 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TSHZ3 | c.3011G>T p.R1004L | Missense Mutation (SNP) | VAF 40/225 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TTC14 | c.1369A>T p.K457* | Nonsense Mutation (SNP) | VAF 19/298 reads (6%) | called by muse, mutect2
- VN1R5 | c.823G>T p.V275L | Missense Mutation (SNP) | VAF 53/436 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- VSIG4 | c.396G>T p.E132D | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2
- WNK3 | c.289G>T p.V97L | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- XKR4 | c.5C>A p.A2D | Missense Mutation (SNP) | VAF 44/355 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- ZFHX4 | c.937C>A p.L313I | Missense Mutation (SNP) | VAF 38/357 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZNF382 | c.138G>T p.V46= | Splice Region (SNP) | VAF 32/313 reads (10%) | called by mutect2, varscan2
- ZNF669 | c.352G>T p.V118L | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ABCA13 | c.5784C>T p.V1928= | Silent (SNP) | VAF 83/748 reads (11%) | catalogued as COSV70041228; called by muse, mutect2, varscan2
- ADGRB3 | c.2286T>G p.L762= | Silent (SNP) | VAF 14/204 reads (7%) | called by muse, mutect2
- ADGRG4 | c.4839G>C p.V1613= | Silent (SNP) | VAF 32/404 reads (8%) | called by muse, mutect2
- ALS2 | c.2874G>T p.T958= | Silent (SNP) | VAF 46/596 reads (8%) | catalogued as rs907072533, COSV51890834; called by muse, mutect2
- ARHGAP22 | c.1197G>A p.A399= | Silent (SNP) | VAF 17/112 reads (15%) | catalogued as rs1471883385; called by muse, mutect2
- ATP11B | c.1848T>C p.H616= | Silent (SNP) | VAF 14/208 reads (7%) | catalogued as rs768245061; called by muse, mutect2
- ATP13A4 | c.2061G>T p.G687= | Silent (SNP) | VAF 56/688 reads (8%) | called by muse, mutect2
- ATP7A | c.516G>T p.V172= | Silent (SNP) | VAF 66/439 reads (15%) | called by muse, mutect2, varscan2
- BAZ2A | c.2077C>T p.L693= | Silent (SNP) | VAF 62/509 reads (12%) | called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.822T>C p.I274= | Silent (SNP) | VAF 30/254 reads (12%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.2394A>T p.V798= (on ENST00000356253 / NM_001366867.1; = p.V786= on NM_000722.4) | Silent (SNP) | VAF 47/542 reads (9%) | called by muse, mutect2
- CEP135 | c.1791A>G p.E597= | Silent (SNP) | VAF 32/241 reads (13%) | catalogued as COSV57259199; called by muse, mutect2, varscan2
- CYSLTR2 | c.471C>A p.I157= | Silent (SNP) | VAF 41/384 reads (11%) | called by muse, mutect2, varscan2
- DCAF12L2 | c.600C>T p.V200= | Silent (SNP) | VAF 53/530 reads (10%) | catalogued as rs771849328, COSV63584441; called by muse, mutect2, varscan2
- DDX46 | c.606C>T p.D202= | Silent (SNP) | VAF 24/110 reads (22%) | catalogued as rs759439661, COSV62800050; called by muse, mutect2, varscan2
- DHCR24 | c.999C>T p.R333= | Silent (SNP) | VAF 54/493 reads (11%) | called by muse, mutect2, varscan2
- DKC1 | c.300C>T p.P100= | Silent (SNP) | VAF 40/452 reads (9%) | catalogued as rs1405744128; called by muse, mutect2
- DPPA4 | c.528G>C p.P176= | Silent (SNP) | VAF 62/672 reads (9%) | called by muse, mutect2
- DPYD | c.588G>T p.G196= | Silent (SNP) | VAF 52/347 reads (15%) | called by muse, mutect2, varscan2
- ELMO2 | c.1158C>T p.D386= | Silent (SNP) | VAF 28/235 reads (12%) | called by muse, mutect2, varscan2
- EPHA3 | c.1149C>G p.L383= | Silent (SNP) | VAF 129/842 reads (15%) | called by muse, mutect2, varscan2
- FAM184B | c.2151G>A p.E717= | Silent (SNP) | VAF 37/180 reads (21%) | called by muse, mutect2, varscan2
- FHOD3 | c.3135A>T p.A1045= (on ENST00000359247 / NM_001281739.3; = p.A1062= on NM_025135.5) | Silent (SNP) | VAF 30/232 reads (13%) | called by muse, mutect2, varscan2
- GALR3 | c.195G>A p.A65= | Silent (SNP) | VAF 26/228 reads (11%) | catalogued as rs1007841925; called by muse, mutect2, varscan2
- GATA3 | c.1320C>A p.T440= | Silent (SNP) | VAF 29/210 reads (14%) | catalogued as COSV100650857, COSV60521687, COSV99062036; called by muse, mutect2, varscan2
- GHR | c.375T>C p.Y125= | Silent (SNP) | VAF 90/524 reads (17%) | catalogued as rs762446451; called by muse, mutect2, varscan2
- HDAC6 | c.27C>A p.T9= | Silent (SNP) | VAF 51/545 reads (9%) | catalogued as rs1017706617; called by muse, mutect2
- HECW1 | c.1269G>A p.T423= | Silent (SNP) | VAF 82/697 reads (12%) | catalogued as rs746205747, COSV101223432; called by muse, mutect2, varscan2
- HNRNPCL1 | c.592C>T p.L198= | Silent (SNP) | VAF 74/618 reads (12%) | called by muse, mutect2, varscan2
- HS6ST2 | c.246G>C p.A82= | Silent (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- HYAL4 | c.1182G>T p.A394= | Silent (SNP) | VAF 66/637 reads (10%) | catalogued as rs138391454; called by muse, mutect2, varscan2
- IGKV1D-42 | c.204C>T p.L68= | Silent (SNP) | VAF 51/327 reads (16%) | called by muse, mutect2, varscan2
- INAVA | c.1626G>T p.P542= | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as rs764975067; called by muse, mutect2, varscan2
- INSC | c.744C>T p.A248= | Silent (SNP) | VAF 62/532 reads (12%) | catalogued as COSV65409528; called by muse, mutect2, varscan2
- KANK3 | c.1173G>T p.A391= | Silent (SNP) | VAF 15/94 reads (16%) | called by muse, mutect2, varscan2
- KCNH1 | c.945G>T p.V315= | Silent (SNP) | VAF 30/324 reads (9%) | called by muse, mutect2
- KCNT2 | c.1482G>A p.L494= | Silent (SNP) | VAF 34/355 reads (10%) | called by muse, mutect2, varscan2
- KIAA1671 | c.1698G>C p.R566= | Silent (SNP) | VAF 40/209 reads (19%) | called by muse, mutect2, varscan2
- KIF21B | c.4530C>T p.L1510= (on ENST00000422435 / NM_001252100.2; = p.L1497= on NM_017596.4) | Silent (SNP) | VAF 26/304 reads (9%) | catalogued as rs150393728; called by muse, mutect2
- KMT2C | c.5841C>A p.S1947= | Silent (SNP) | VAF 54/419 reads (13%) | called by muse, mutect2, varscan2
- KRT33A | c.81C>T p.H27= | Silent (SNP) | VAF 28/537 reads (5%) | catalogued as rs201833052, COSV50365406; called by muse, mutect2
- LIMCH1 | c.777G>A p.E259= | Silent (SNP) | VAF 107/913 reads (12%) | catalogued as rs1276044106, COSV58286779; called by muse, mutect2, varscan2
- MAGED2 | c.165G>C p.V55= | Silent (SNP) | VAF 26/334 reads (8%) | catalogued as rs766564460; called by muse, mutect2
- MAPK8IP3 | c.2001C>T p.S667= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs1324301558; called by muse, mutect2, varscan2
- MSL3 | c.1092C>T p.S364= (on ENST00000312196 / NM_078629.4; = p.S198= on NM_006800.4) | Silent (SNP) | VAF 20/218 reads (9%) | called by muse, mutect2
- MYH4 | c.3207C>A p.S1069= | Silent (SNP) | VAF 24/265 reads (9%) | catalogued as COSV55119654; called by muse, mutect2
- MYOM2 | c.1557T>G p.A519= | Silent (SNP) | VAF 39/320 reads (12%) | called by muse, mutect2, varscan2
- NARF | c.243C>T p.N81= | Silent (SNP) | VAF 25/164 reads (15%) | called by muse, mutect2, varscan2
- NFATC3 | c.1950A>T p.I650= | Silent (SNP) | VAF 29/337 reads (9%) | called by muse, mutect2
- NSMCE1 | c.225C>T p.V75= | Silent (SNP) | VAF 50/525 reads (10%) | catalogued as COSV63864281; called by muse, mutect2
- NXF3 | c.564T>C p.A188= | Silent (SNP) | VAF 42/431 reads (10%) | called by muse, mutect2
- NYAP1 | c.285G>T p.G95= | Silent (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- OBSCN | c.14058G>A p.T4686= | Silent (SNP) | VAF 54/413 reads (13%) | catalogued as rs746997337, COSV52810645; called by muse, mutect2, varscan2
- OR10K2 | c.468A>G p.A156= | Silent (SNP) | VAF 112/952 reads (12%) | catalogued as COSV100149411; called by muse, mutect2, varscan2
- OR51C1P | c.372G>C p.V124= | Silent (SNP) | VAF 40/346 reads (12%) | called by muse, mutect2, varscan2
- OR51V1 | c.174G>A p.L58= | Silent (SNP) | VAF 22/148 reads (15%) | catalogued as COSV58314816; called by muse, mutect2, varscan2
- OR8J3 | c.729G>A p.S243= | Silent (SNP) | VAF 20/201 reads (10%) | catalogued as rs774862778, COSV56879581, COSV56879736; called by muse, mutect2, varscan2
- PBXIP1 | c.918A>G p.L306= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs1196339330; called by muse, mutect2, varscan2
- PDILT | c.1329C>T p.A443= | Silent (SNP) | VAF 65/570 reads (11%) | called by muse, mutect2, varscan2
- PFKFB1 | c.972G>A p.K324= | Silent (SNP) | VAF 20/194 reads (10%) | called by muse, mutect2, varscan2
- PIP5K1B | c.690C>T p.F230= | Silent (SNP) | VAF 38/560 reads (7%) | catalogued as COSV55242910; called by muse, mutect2
- PIR | c.771G>T p.V257= | Silent (SNP) | VAF 37/291 reads (13%) | called by muse, mutect2, varscan2
- PLXNB2 | c.4476G>A p.E1492= | Silent (SNP) | VAF 8/125 reads (6%) | called by muse, mutect2
- PRKCG | c.519C>A p.I173= | Silent (SNP) | VAF 30/520 reads (6%) | called by muse, mutect2
- PRKD2 | c.1326G>A p.P442= | Silent (SNP) | VAF 54/151 reads (36%) | catalogued as rs772539966, COSV52186054; called by muse, varscan2
- PUM2 | c.1500G>C p.R500= | Silent (SNP) | VAF 40/319 reads (13%) | called by muse, varscan2
- RAB38 | c.594A>T p.T198= | Silent (SNP) | VAF 57/482 reads (12%) | called by muse, mutect2, varscan2
- RBM45 | c.669A>T p.P223= | Silent (SNP) | VAF 33/208 reads (16%) | called by muse, mutect2, varscan2
- RGS11 | c.123G>A p.Q41= (on ENST00000397770 / NM_183337.3; = p.Q20= on NM_003834.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- RGS8 | c.516G>T p.L172= (on ENST00000367556 / NM_001369564.2; = p.L190= on NM_033345.3) | Silent (SNP) | VAF 32/238 reads (13%) | called by muse, mutect2, varscan2
- RIMS2 | c.2859C>A p.P953= (on ENST00000666250 / NM_001348490.2; = p.P761= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 41/323 reads (13%) | called by muse, mutect2, varscan2
- SCPEP1 | c.234A>T p.P78= | Silent (SNP) | VAF 67/520 reads (13%) | called by muse, mutect2, varscan2
- SLC9A9 | c.825G>T p.V275= | Silent (SNP) | VAF 53/698 reads (8%) | called by muse, mutect2
- SP140 | c.657T>C p.G219= | Silent (SNP) | VAF 18/228 reads (8%) | catalogued as COSV59454077; called by muse, mutect2
- TEX13A | c.822A>C p.T274= | Silent (SNP) | VAF 52/622 reads (8%) | called by muse, mutect2
- TEX2 | c.969A>G p.S323= | Silent (SNP) | VAF 79/736 reads (11%) | called by muse, mutect2, varscan2
- TMEM132E | c.798G>A p.S266= (on ENST00000321639; = p.S356= on NM_001304438.2) | Silent (SNP) | VAF 24/193 reads (12%) | catalogued as rs201228041; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.486C>A p.A162= | Silent (SNP) | VAF 52/514 reads (10%) | called by muse, mutect2
- TPO | c.1536C>A p.P512= | Silent (SNP) | VAF 42/320 reads (13%) | called by muse, mutect2, varscan2
- TSHZ3 | c.3012G>T p.R1004= | Silent (SNP) | VAF 40/222 reads (18%) | catalogued as rs1343115417; called by muse, mutect2, varscan2
- TTN | c.18831G>A p.K6277= (on ENST00000591111; = p.K5350= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/155 reads (13%) | catalogued as COSV59914907; called by muse, mutect2, varscan2
- UNCX | c.927G>A p.S309= | Silent (SNP) | VAF 15/91 reads (16%) | called by muse, mutect2, varscan2
- VIPR1 | c.417C>T p.Y139= | Silent (SNP) | VAF 18/173 reads (10%) | catalogued as rs1297692879, COSV100285542; called by muse, mutect2
- ZNF280A | c.420G>C p.S140= | Silent (SNP) | VAF 69/359 reads (19%) | called by muse, mutect2, varscan2
- ZNF33B | c.150A>C p.S50= | Silent (SNP) | VAF 17/134 reads (13%) | called by muse, mutect2
- ZNF727 | c.12A>T p.L4= | Silent (SNP) | VAF 39/419 reads (9%) | called by muse, mutect2
- AC114741.1 | n.409G>A | RNA (SNP) | VAF 34/323 reads (11%) | called by muse, mutect2, varscan2
- AC134312.1 | n.446G>T | RNA (SNP) | VAF 12/107 reads (11%) | called by muse, mutect2, varscan2
- AC136759.1 | n.1193C>A | RNA (SNP) | VAF 86/620 reads (14%) | catalogued as rs1484129557; called by mutect2, varscan2
- AC244394.2 | n.838G>A | RNA (SNP) | VAF 58/527 reads (11%) | called by muse, mutect2, varscan2
- ACTG1 | c.-400C>T | 5'UTR (SNP) | VAF 14/88 reads (16%) | catalogued as rs552393684, COSV59510733; ClinVar: likely benign; called by muse, varscan2
- AL353804.4 | chrX:73825868 C>T | 5'Flank (SNP) | VAF 32/332 reads (10%) | called by muse, mutect2
- AWAT2 | c.648-57G>T | Intron (SNP) | VAF 52/596 reads (9%) | called by muse, mutect2
- CHAT | c.*9A>T | 3'UTR (SNP) | VAF 72/715 reads (10%) | called by muse, mutect2
- CSAG1 | c.-16C>G | 5'UTR (SNP) | VAF 32/301 reads (11%) | called by muse, mutect2, varscan2
- DCHS2 | n.7363G>T | RNA (SNP) | VAF 44/579 reads (8%) | called by muse, mutect2
- DPPA3P2 | n.572G>A | RNA (SNP) | VAF 141/1188 reads (12%) | catalogued as rs748760700; called by muse, mutect2, varscan2
- DRD2 | c.723+33T>C | Intron (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2
- FAM161A | c.*1548G>T | 3'UTR (SNP) | VAF 9/101 reads (9%) | called by muse, mutect2
- KCNMA1 | c.2266+5758T>A | Intron (SNP) | VAF 43/539 reads (8%) | called by muse, mutect2
- KLRC1 | chr12:10442265 C>G | 3'Flank (SNP) | VAF 16/196 reads (8%) | called by muse, mutect2
- LINC00868 | n.740A>G | RNA (SNP) | VAF 44/548 reads (8%) | called by muse, mutect2
- LYPD3 | c.382+56G>C | Intron (SNP) | VAF 14/306 reads (5%) | called by muse, mutect2
- MTMR9 | c.292-2101C>T | Intron (SNP) | VAF 26/430 reads (6%) | catalogued as rs757695835; called by muse, mutect2
- MYBPC1 | c.2282-9T>A | Intron (SNP) | VAF 88/743 reads (12%) | called by muse, mutect2, varscan2
- NECTIN3-AS1 | n.1172+30G>T | Intron (SNP) | VAF 30/318 reads (9%) | called by muse, mutect2
- OR2M1P | n.500C>T | RNA (SNP) | VAF 65/594 reads (11%) | called by muse, mutect2, varscan2
- OR4F13P | n.925C>A | RNA (SNP) | VAF 36/550 reads (7%) | called by muse, mutect2
- RAD51D | c.345+40G>T | Intron (SNP) | VAF 75/493 reads (15%) | called by muse, mutect2, varscan2
- RBM3 | c.211-63C>T | Intron (SNP) | VAF 66/893 reads (7%) | called by muse, mutect2
- RPGR | c.2520+1508A>T | Intron (SNP) | VAF 71/543 reads (13%) | called by muse, mutect2, varscan2
- RPL23A | c.210-134A>G | Intron (SNP) | VAF 35/267 reads (13%) | called by muse, mutect2, varscan2
- SCD5 | c.569+19700C>A | Intron (SNP) | VAF 92/973 reads (9%) | called by muse, mutect2
- SERPINB5 | c.567+107G>C | Intron (SNP) | VAF 25/145 reads (17%) | called by mutect2, varscan2
- SGCE | c.499-37A>G | Intron (SNP) | VAF 24/247 reads (10%) | called by muse, mutect2
- SNORD113-8 | n.23G>T | RNA (SNP) | VAF 12/180 reads (7%) | catalogued as rs1311998665; called by muse, mutect2
- SOSTDC1 | c.205+1120A>G | Intron (SNP) | VAF 45/458 reads (10%) | catalogued as rs1421545318; called by muse, mutect2
- TRIM48 | c.-42C>G | 5'UTR (SNP) | VAF 61/743 reads (8%) | called by muse, mutect2
- TTN | c.10360+1466T>C | Intron (SNP) | VAF 26/474 reads (5%) | catalogued as rs1322761163; called by muse, mutect2
- UBBP4 | n.939A>C | RNA (SNP) | VAF 96/769 reads (12%) | called by muse, mutect2, varscan2
- UBTFL2 | n.310A>T | RNA (SNP) | VAF 123/1039 reads (12%) | called by muse, mutect2, varscan2
- UGT1A6 | c.862-23387G>T | Intron (SNP) | VAF 60/532 reads (11%) | catalogued as COSV59389756; called by muse, mutect2, varscan2
- UGT2B27P | n.140C>A | RNA (SNP) | VAF 54/604 reads (9%) | called by muse, mutect2
- UMPS | c.*3707C>G | 3'UTR (SNP) | VAF 13/110 reads (12%) | called by muse, mutect2, varscan2
- WASF4P | n.441C>G | RNA (SNP) | VAF 58/792 reads (7%) | called by muse, mutect2
- YLPM1 | c.*138G>A | 3'UTR (SNP) | VAF 34/448 reads (8%) | called by muse, mutect2
